TCGA case TCGA-EL-A3ZM — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/04dc8ee3-ec93-4b56-a546-f96746f8122f

Demographics
Sex at birth: male; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.2 years (21,987 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T4a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 1,096 days (3.0 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Extrathyroid extension: Moderate/Advanced (T4a); Lymph nodes positive: 7; Lymph nodes tested: 27; Measurement unit: Centimeters; Tumor depth measurement: 3.9; Tumor length measurement: 5.7; Tumor width measurement: 4.1.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 49 days; Days to treatment end: 90 days; Treatment dose: 60 Gy; Number of fractions: 30; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 147 days; Days to treatment end: 147 days; Treatment dose: 150 mCi; Number of fractions: 1; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 150 mCi; Pretreatment: Thyroxine Withdrawal.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Prescribed dose: 60; Prescribed dose units: Gy; Radiosensitizing agent: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,096 days (3.0 years); Disease response: Tumor Free.
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Follow-up contact recording only the day: within 3 months of surgery.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EL-A3ZM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 240 mg.
  Slide TCGA-EL-A3ZM-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EL-A3ZM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EL-A3ZM-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 230 mg.
  Slide TCGA-EL-A3ZM-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: No; I 131 radiation treatment cumulative dose: 150 mCi; Radiation therapy xrt method prep: Imrt; Radiation therapy xrt dose: 60 Gy; Radiation therapy xrt sensitizers: No; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation treatment cumulative dose: 150 mCi; Radiation therapy xrt method prep: Imrt; Radiation therapy xrt dose: 60 Gy; Radiation therapy xrt sensitizers: No; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: Yes; Tumor status: Tumor free; I 131 radiation treatment cumulative dose: 150 mCi; Radiation therapy xrt method prep: Imrt; Radiation therapy xrt dose: 60 Gy; Radiation therapy xrt sensitizers: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,096 days; disease-specific survival: no event (censored), 1,096 days; progression-free interval: no event (censored), 1,096 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EL-A3ZM-01A-12D-A23L-01): tumor purity 0.85, ploidy 2.14, whole-genome doublings 0.
